CPTAC case C3L-04391 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d4fba188-8ca4-44c0-a9e2-67bcff29b99a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1948; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 70.2 years (25,641 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,792 days (4.9 years); Progression or recurrence: no; Days to last follow up: 1,792 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.8 cm (a second GDC size field records 6.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 10; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 301 days; Disease response: Tumor Free.
- Days to follow up: 635 days (1.7 years); Disease response: Tumor Free.
- Days to follow up: 994 days (2.7 years); Disease response: Complete Response.
- Days to follow up: 1,155 days (3.2 years); Disease response: Tumor Free.
- Days to follow up: 1,414 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,792 days (4.9 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 70.76 kg; Height: 175.26 cm; BMI: 23.03; FEV1/FVC after bronchodilator (%): 70; FEV1/FVC before bronchodilator (%): 66; FEV1 before bronchodilator (% of reference): 98.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 10; Cigarettes per day: 20; Tobacco smoking onset year: 1968; Tobacco smoking quit year: 1978; Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Exposure duration years: 10.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04391-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 238 mg; Time between excision and freezing: 22 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04391-22: Section location: Right Upper Lobe; Percent tumor nuclei: 55; Percent necrosis: 5.
- Sample C3L-04391-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 141 mg; Time between excision and freezing: 22 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-04391-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
